Somatic mutation profile of tumor specimen MP2PRT-PAULKT-TMP1-A (aliquot MP2PRT-PAULKT-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAULKT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,619 days).
Specimen MP2PRT-PAULKT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60fc9d0e-fb0b-482b-b68c-4320479eb2fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULKT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULKT-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6488ada9-6b6c-4d96-ac3d-c1e46284c8e8

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AC024598.1 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 108/312 reads (35%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.006); catalogued as COSV99047860; called by muse, mutect2, varscan2
- H2BW2 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs782568310, COSV54583457; called by muse, mutect2
- LRRC23 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs1555139671; called by muse, mutect2, varscan2
- SAMHD1 | c.1588G>A p.A530T (on ENST00000262878 / NM_001363729.2; = p.A565T on NM_015474.4) | Missense Mutation (SNP) | VAF 154/452 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs779491090, CM150578, COSV53428046, COSV53431969; called by muse, mutect2, varscan2
- SHROOM4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 239/385 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs782548063, COSV56792899; called by muse, mutect2, varscan2
- CYP2A6 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 18/598 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EYS | c.3175C>G p.L1059V | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HDAC2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4A11 | c.93G>A p.L31= | Silent (SNP) | VAF 116/532 reads (22%) | called by muse, mutect2, varscan2
- FAM47C | c.123G>A p.P41= | Silent (SNP) | VAF 299/378 reads (79%) | catalogued as rs782696018, COSV63725468, COSV63731070; called by muse, mutect2, varscan2
- RIMBP2 | c.2106C>T p.A702= | Silent (SNP) | VAF 159/532 reads (30%) | catalogued as rs149905625; called by muse, mutect2, varscan2
- ZC3H4 | c.3768C>T p.F1256= | Silent (SNP) | VAF 233/675 reads (35%) | catalogued as rs746074614; called by muse, mutect2, varscan2
